Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6TX, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6TX-01A (Primary Tumor).

Histomorphology shows oligodendroglial differentiation. Mitotic activity present.
Proliferation 10%,

Diagnosis

Anaplastic oligodendroglioma WHO grade III

case
Oligodendroglioma,
grade III 9451/3
path
Oligodendroglioma,
anaplastic 9451/3 NO
Site Brain, supratentorial
C71.0
JW 7/25/13

Untranslated original report
is housed at the BCR.

Source: NCI Genomic Data Commons file 5fa5fc3a-cbca-446f-9c81-6a2eff2b91c7 (TCGA-S9-A6TX.B2F18877-6F79-40BE-8F35-38713A54DD58.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).